Somatic mutation profile of cancer-model specimen HCM-CSHL-0857-C19-85M (3D Organoid, passage 4; aliquot HCM-CSHL-0857-C19-85M-01D-A881-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0857-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.9 years (26,244 days).
Specimen HCM-CSHL-0857-C19-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01c00acf-2544-48a2-970c-0981aba2c1ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0857-C19-11A (Solid Tissue Normal), aliquot HCM-CSHL-0857-C19-11A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/606a4b50-d7f7-4f4c-8141-51f284b02ac5

The open-access MAF lists 172 somatic variants for this specimen: 126 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 43, Nonsense Mutation 7, Frame Shift Del 4, Frame Shift Ins 2, Splice Region 2, In Frame Del 2, Splice Site 2, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3340C>T p.R1114* | Nonsense Mutation (SNP) | VAF 159/438 reads (36%) | hotspot (GDC flag); catalogued as rs121913331, CM920048, COSV57321465, COSV57335215, COSV57385441; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- APC | c.3956del p.P1319Lfs*2 | Frame Shift Del (DEL) | VAF 260/549 reads (47%) | catalogued as rs1057517558, COSV57356047, COSV57400437; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CYP17A1 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 172/568 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs104894149, CM024701, COSV64005060; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.398T>G p.M133R | Missense Mutation (SNP) | VAF 298/299 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.129); catalogued as CM910373, CM973400, COSV52744834, COSV52795528, COSV52821486, COSV52852024; called by muse, varscan2
- ABCA12 | c.6424C>T p.R2142C (on ENST00000272895 / NM_173076.3; = p.R1824C on NM_015657.3) | Missense Mutation (SNP) | VAF 162/401 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.72); catalogued as rs758122196, COSV55948948; called by muse, mutect2, varscan2
- ACSM4 | c.524T>C p.V175A | Missense Mutation (SNP) | VAF 151/305 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1436222747; called by muse, mutect2, varscan2
- BNC2 | c.1687C>A p.L563I | Missense Mutation (SNP) | VAF 114/382 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV66150559; called by mutect2, varscan2
- BTBD3 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 502/708 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs930540638, COSV54778752; called by muse, mutect2, varscan2
- CACNA1E | c.5237G>A p.R1746H | Missense Mutation (SNP) | VAF 124/395 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62391346; called by muse, mutect2, varscan2
- CALHM1 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 266/408 reads (65%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.874); catalogued as rs202160393, COSV53294861; called by muse, varscan2
- DLGAP2 | c.2314A>T p.S772C | Missense Mutation (SNP) | VAF 177/182 reads (97%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV70099426; called by muse, mutect2, varscan2
- ELAVL3 | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 288/488 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100820737; called by muse, mutect2, varscan2
- FABP4 | c.283G>A p.V95M | Missense Mutation (SNP) | VAF 117/550 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs1450734289; called by muse, mutect2, varscan2
- FCGR3A | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 140/513 reads (27%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs1031388823, COSV100914641; called by muse, mutect2, varscan2
- FILIP1L | c.3259C>A p.L1087M (on ENST00000354552 / NM_182909.3; = p.L847M on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/407 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs772465470; called by muse, mutect2, varscan2
- GASK1A | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 22/528 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.011); catalogued as COSV99826541; called by muse, mutect2
- GRIN2A | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 227/985 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs143833346; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2B | c.4322G>A p.R1441H | Missense Mutation (SNP) | VAF 226/426 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs200903876; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HTR1A | c.91G>A p.V31M | Missense Mutation (SNP) | VAF 158/496 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs764663330; called by muse, mutect2, varscan2
- ITGB8 | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 286/667 reads (43%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.999); catalogued as rs1228157455; called by muse, mutect2, varscan2
- KCNH5 | c.2066G>A p.R689H | Missense Mutation (SNP) | VAF 134/277 reads (48%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.608); catalogued as rs533454331, COSV59757653, COSV59765420; called by muse, mutect2, varscan2
- KYAT3 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 164/543 reads (30%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.999); catalogued as rs759620693, COSV53099540; called by muse, mutect2, varscan2
- LAIR1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 256/800 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs201618231, COSV57305754, COSV57307996; called by muse, mutect2, varscan2
- LILRA1 | c.181T>A p.Y61N | Missense Mutation (SNP) | VAF 162/446 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV99070432; called by muse, mutect2, varscan2
- LY6K | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 202/951 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.005); catalogued as COSV99456542; called by muse, mutect2, varscan2
- MRPL55 | c.218G>A p.R73H | Missense Mutation (SNP) | VAF 117/268 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs760580888; called by muse, mutect2, varscan2
- OPCML | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 113/431 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs749718972, COSV59402476; called by muse, mutect2, varscan2
- OPLAH | c.2533C>T p.R845W | Missense Mutation (SNP) | VAF 677/863 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs367992509; called by muse, mutect2, varscan2
- PCDHA13 | c.1136C>G p.S379C | Missense Mutation (SNP) | VAF 255/419 reads (61%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs199942713, COSV56482025; called by muse, mutect2, varscan2
- PHC1 | c.1598G>A p.R533Q | Missense Mutation (SNP) | VAF 41/218 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs878853029; ClinVar: likely benign; called by muse, mutect2, varscan2
- PLEKHA2 | c.1144C>T p.R382C | Missense Mutation (SNP) | VAF 174/683 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as rs758412940; called by muse, mutect2, varscan2
- POTEM | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.245); catalogued as rs531611167, COSV101304489; called by mutect2, varscan2
- PRG4 | c.2513C>T p.T838I | Missense Mutation (SNP) | VAF 171/579 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs777305605; called by muse, mutect2, varscan2
- PTPRS | c.5392C>T p.R1798C | Missense Mutation (SNP) | VAF 11/380 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1477121983; called by muse, mutect2
- RASSF2 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 104/466 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV101040888; called by muse, mutect2, varscan2
- RBFOX1 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 91/454 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV60954857, COSV60986955; called by muse, mutect2, varscan2
- RBM12 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 136/776 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100467748; called by muse, mutect2, varscan2
- RYR2 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 258/392 reads (66%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.877); catalogued as rs368974917; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 136/474 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs770463034, COSV56572969; called by muse, mutect2, varscan2
- SORCS1 | c.3475C>T p.R1159W | Missense Mutation (SNP) | VAF 160/278 reads (58%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.352); catalogued as rs773862245, COSV53899675; called by muse, mutect2, varscan2
- SPTLC3 | c.568G>T p.V190L | Missense Mutation (SNP) | VAF 82/492 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs756668458; called by muse, mutect2, varscan2
- STIP1 | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 86/167 reads (51%) | catalogued as COSV59438877; called by muse, mutect2, varscan2
- SYF2 | c.587A>G p.Y196C | Missense Mutation (SNP) | VAF 96/298 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs545105070; called by muse, mutect2, varscan2
- TMEM132C | c.2326G>A p.A776T | Missense Mutation (SNP) | VAF 329/531 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.324); catalogued as rs985061554, COSV59424989; called by muse, mutect2, varscan2
- TMEM231 | c.520G>A p.G174R (on ENST00000258173 / NM_001077418.3; = p.G203R on NM_001077416.2) | Missense Mutation (SNP) | VAF 271/541 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763194213, COSV50738405; called by muse, mutect2, varscan2
- TRMT1L | c.206T>G p.L69R | Missense Mutation (SNP) | VAF 131/387 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.218); catalogued as COSV62259414; called by muse, mutect2, varscan2
- ZCCHC2 | c.1340C>T p.A447V | Missense Mutation (SNP) | VAF 137/141 reads (97%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.994); catalogued as COSV54041842; called by muse, mutect2, varscan2
- ZNF492 | c.1193G>T p.C398F | Missense Mutation (SNP) | VAF 83/742 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71762118; called by mutect2, varscan2
- ZNF716 | c.391A>T p.S131C | Missense Mutation (SNP) | VAF 61/312 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV70779306, COSV70780167; called by mutect2, varscan2
- A2M | c.1193C>A p.T398N | Missense Mutation (SNP) | VAF 149/317 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ADCY1 | c.2257del p.M753* | Frame Shift Del (DEL) | VAF 200/816 reads (25%) | called by pindel, varscan2
- ADGRL2 | c.3923T>C p.L1308S (on ENST00000370717 / NM_001366005.1; = p.L1252S on NM_012302.4) | Missense Mutation (SNP) | VAF 155/157 reads (99%) | SIFT tolerated (0.48); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADGRL4 | c.775_776insG p.F259Cfs*3 | Frame Shift Ins (INS) | VAF 30/42 reads (71%) | called by mutect2, pindel, varscan2
- AGXT | c.1071G>A p.K357= | Splice Region (SNP) | VAF 176/363 reads (48%) | called by muse, mutect2, varscan2
- ANKS1B | c.2068A>T p.R690* | Nonsense Mutation (SNP) | VAF 165/583 reads (28%) | called by muse, mutect2, varscan2
- APC | c.7855G>A p.E2619K | Missense Mutation (SNP) | VAF 227/380 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ASAH2 | c.1757A>G p.Y586C | Missense Mutation (SNP) | VAF 84/281 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BCHE | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0); called by mutect2, varscan2
- BCOR | c.4537G>A p.V1513M (on ENST00000378444 / NM_001123385.2; = p.V1479M on NM_017745.6) | Missense Mutation (SNP) | VAF 284/583 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CALHM6 | c.196C>A p.L66M | Missense Mutation (SNP) | VAF 51/901 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDH17 | c.1731G>C p.E577D | Missense Mutation (SNP) | VAF 138/744 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDK1 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 105/363 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC16A | c.344-1G>C p.X115_splice | Splice Site (SNP) | VAF 66/260 reads (25%) | called by muse, mutect2
- CSTF1 | c.43T>C p.Y15H | Missense Mutation (SNP) | VAF 158/1113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CUL1 | c.1948-1G>A p.X650_splice | Splice Site (SNP) | VAF 109/380 reads (29%) | called by muse, mutect2, varscan2
- CYP7A1 | c.711A>T p.K237N | Missense Mutation (SNP) | VAF 156/808 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DGKH | c.477A>T p.R159S | Missense Mutation (SNP) | VAF 263/399 reads (66%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1158_1193del p.P387_I398del | In Frame Del (DEL) | VAF 60/244 reads (25%) | called by mutect2, pindel, varscan2
- EPAS1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 150/602 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F5 | c.3545G>T p.W1182L | Missense Mutation (SNP) | VAF 234/370 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.188); called by muse, varscan2
- FAT1 | c.4542_4543del p.T1516Ffs*2 | Frame Shift Del (DEL) | VAF 122/402 reads (30%) | called by pindel, varscan2
- FOXM1 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 159/347 reads (46%) | called by muse, mutect2, varscan2
- FOXRED1 | c.1324C>T p.L442F | Missense Mutation (SNP) | VAF 216/664 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GABRE | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 185/263 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- GCLM | c.673A>T p.S225C | Missense Mutation (SNP) | VAF 96/327 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- HCN1 | c.2474C>T p.T825M | Missense Mutation (SNP) | VAF 192/524 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IQGAP2 | c.1177C>A p.Q393K | Missense Mutation (SNP) | VAF 237/423 reads (56%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ITGAM | c.2643T>G p.N881K (on ENST00000648685 / NM_001145808.2; = p.N880K on NM_000632.4) | Missense Mutation (SNP) | VAF 112/436 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); called by mutect2, varscan2
- KBTBD7 | c.1421T>A p.F474Y | Missense Mutation (SNP) | VAF 134/427 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- KIF13B | c.2374G>C p.D792H | Missense Mutation (SNP) | VAF 128/128 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KIRREL2 | c.760C>G p.P254A | Missense Mutation (SNP) | VAF 107/454 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT27 | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 132/367 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- LCOR | c.2410A>T p.K804* | Nonsense Mutation (SNP) | VAF 122/403 reads (30%) | called by muse, mutect2, varscan2
- LRBA | c.6521_6526del p.K2174_V2176delinsM | In Frame Del (DEL) | VAF 61/168 reads (36%) | called by mutect2, pindel, varscan2
- LRRTM4 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 235/463 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MARK4 | c.968C>G p.T323R | Missense Mutation (SNP) | VAF 144/418 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MNT | c.1382G>T p.G461V | Missense Mutation (SNP) | VAF 237/471 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- MOCOS | c.470G>C p.G157A | Missense Mutation (SNP) | VAF 125/402 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTARC1 | c.593T>C p.L198S | Missense Mutation (SNP) | VAF 137/265 reads (52%) | SIFT tolerated (0.79); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MYO7A | c.5585A>C p.K1862T | Missense Mutation (SNP) | VAF 217/2928 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.602); called by muse, mutect2
- NAV3 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBR1 | c.1642T>A p.Y548N | Missense Mutation (SNP) | VAF 116/339 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFKB2 | c.1510A>G p.I504V | Missense Mutation (SNP) | VAF 289/461 reads (63%) | SIFT tolerated (0.83); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- NTM | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 151/624 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR4C16 | c.68A>C p.K23T | Missense Mutation (SNP) | VAF 126/418 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- OR7G1 | c.776A>C p.Y259S | Missense Mutation (SNP) | VAF 194/568 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- PCDHA11 | c.253T>A p.F85I | Missense Mutation (SNP) | VAF 255/707 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- PCDHAC1 | c.964A>G p.S322G | Missense Mutation (SNP) | VAF 150/506 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PIEZO1 | c.5336C>T p.T1779I | Missense Mutation (SNP) | VAF 186/911 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- POTEG | c.349G>C p.V117L | Missense Mutation (SNP) | VAF 223/2055 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.346); called by muse, varscan2
- PPP4R3A | c.81_115del p.S28Pfs*6 | Frame Shift Del (DEL) | VAF 66/447 reads (15%) | called by mutect2, varscan2
- PRRC2B | c.3691A>G p.S1231G | Missense Mutation (SNP) | VAF 172/558 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RMDN1 | c.454A>G p.R152G | Missense Mutation (SNP) | VAF 123/604 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- RREB1 | c.3310T>A p.L1104I | Missense Mutation (SNP) | VAF 230/678 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR3 | c.2847G>T p.K949N | Missense Mutation (SNP) | VAF 106/218 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- SAMD14 | c.121G>A p.G41S | Missense Mutation (SNP) | VAF 291/842 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- SCAP | c.1590C>G p.I530M | Missense Mutation (SNP) | VAF 146/456 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SCTR | c.924T>A p.I308= | Splice Region (SNP) | VAF 77/337 reads (23%) | called by muse, mutect2, varscan2
- STAM | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 126/403 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by mutect2, varscan2
- TBCK | c.2339T>C p.F780S (on ENST00000273980 / NM_001163436.4; = p.F717S on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/380 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENM1 | c.4205G>A p.R1402H | Missense Mutation (SNP) | VAF 91/315 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TMPRSS9 | c.1477A>C p.T493P (on ENST00000648592; = p.T459P on NM_182973.2) | Missense Mutation (SNP) | VAF 182/661 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TNN | c.1679A>C p.K560T | Missense Mutation (SNP) | VAF 142/455 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- TPBGL | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 182/909 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM47 | c.448T>C p.S150P | Missense Mutation (SNP) | VAF 245/862 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- UGCG | c.960G>A p.M320I | Missense Mutation (SNP) | VAF 156/478 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.10624G>T p.E3542* | Nonsense Mutation (SNP) | VAF 104/222 reads (47%) | called by mutect2, varscan2
- WDR87 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 160/433 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- XIRP2 | c.9062C>A p.A3021D (on ENST00000628543; = p.A3196D on NM_152381.6) | Missense Mutation (SNP) | VAF 56/696 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.107); called by muse, mutect2
- ZC3H11B | c.1519T>G p.L507V | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ZCCHC14 | c.1658A>C p.K553T (on ENST00000268616; = p.K690T on NM_015144.3) | Missense Mutation (SNP) | VAF 180/960 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZCCHC2 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 135/139 reads (97%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZIM2 | c.1491G>C p.Q497H | Missense Mutation (SNP) | VAF 124/405 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF292 | c.3498_3499insG p.F1167Vfs*54 | Frame Shift Ins (INS) | VAF 141/520 reads (27%) | called by mutect2, pindel, varscan2
- ZNF587 | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 164/495 reads (33%) | called by muse, varscan2
- ZNF804A | c.2003G>C p.S668T | Missense Mutation (SNP) | VAF 86/411 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ABCA7 | c.1917G>A p.T639= | Silent (SNP) | VAF 491/758 reads (65%) | catalogued as rs746473132; called by muse, mutect2, varscan2
- ABCC12 | c.1656C>A p.I552= | Silent (SNP) | VAF 135/800 reads (17%) | called by muse, mutect2, varscan2
- AHDC1 | c.1281C>T p.A427= | Silent (SNP) | VAF 453/727 reads (62%) | catalogued as rs753828677; called by muse, mutect2, varscan2
- ASXL2 | c.3069C>T p.T1023= | Silent (SNP) | VAF 159/645 reads (25%) | called by muse, mutect2, varscan2
- B3GNT7 | c.543C>A p.S181= | Silent (SNP) | VAF 445/1029 reads (43%) | called by muse, mutect2, varscan2
- CELSR1 | c.8955G>A p.R2985= | Silent (SNP) | VAF 226/454 reads (50%) | called by muse, varscan2
- CFAP92 | c.792C>T p.H264= | Silent (SNP) | VAF 96/341 reads (28%) | catalogued as COSV54048057; called by muse, mutect2, varscan2
- CRYBG3 | c.8262C>A p.I2754= | Silent (SNP) | VAF 125/337 reads (37%) | catalogued as COSV51714964; called by muse, mutect2, varscan2
- DCHS2 | c.850C>T p.L284= | Silent (SNP) | VAF 71/437 reads (16%) | called by muse, mutect2, varscan2
- ESX1 | c.1083G>A p.P361= | Silent (SNP) | VAF 104/486 reads (21%) | catalogued as rs781810749, COSV65424091; called by muse, varscan2
- FAM170B | c.142C>A p.R48= | Silent (SNP) | VAF 121/410 reads (30%) | called by muse, mutect2, varscan2
- FBXL6 | c.1185G>A p.A395= | Silent (SNP) | VAF 181/811 reads (22%) | catalogued as rs782288913, COSV57352518; called by muse, mutect2, varscan2
- FLNB | c.6708C>T p.A2236= | Silent (SNP) | VAF 149/453 reads (33%) | catalogued as rs532347120; called by muse, mutect2, varscan2
- GOLGA4 | c.5554T>C p.L1852= | Silent (SNP) | VAF 126/402 reads (31%) | called by muse, mutect2, varscan2
- GRIK2 | c.2511G>T p.V837= | Silent (SNP) | VAF 127/376 reads (34%) | catalogued as rs1202805919; called by muse, mutect2, varscan2
- H2AC4 | c.126G>A p.E42= | Silent (SNP) | VAF 134/396 reads (34%) | catalogued as COSV52519191; called by muse, mutect2, varscan2
- HECW1 | c.321C>T p.D107= | Silent (SNP) | VAF 219/558 reads (39%) | catalogued as rs375404889; called by muse, mutect2, varscan2
- HOXD4 | c.60C>T p.C20= | Silent (SNP) | VAF 325/671 reads (48%) | catalogued as COSV60460167; called by muse, mutect2, varscan2
- IFT140 | c.3780G>T p.R1260= | Silent (SNP) | VAF 164/752 reads (22%) | catalogued as COSV100794315; called by muse, mutect2, varscan2
- LCOR | c.2409G>A p.K803= | Silent (SNP) | VAF 122/405 reads (30%) | called by muse, mutect2, varscan2
- LYST | c.5913G>A p.Q1971= | Silent (SNP) | VAF 267/365 reads (73%) | catalogued as COSV101089949; called by muse, mutect2, varscan2
- MMP21 | c.228G>A p.P76= | Silent (SNP) | VAF 239/723 reads (33%) | catalogued as COSV64290555; called by muse, mutect2, varscan2
- MUC16 | c.36615C>A p.T12205= | Silent (SNP) | VAF 74/222 reads (33%) | called by muse, mutect2, varscan2
- NDFIP2 | c.618A>G p.Q206= | Silent (SNP) | VAF 63/197 reads (32%) | called by muse, mutect2, varscan2
- NUMA1 | c.1617C>G p.L539= | Silent (SNP) | VAF 186/759 reads (25%) | called by muse, mutect2, varscan2
- OR14A2 | c.216G>A p.V72= | Silent (SNP) | VAF 119/385 reads (31%) | called by muse, mutect2, varscan2
- OR5P3 | c.795C>T p.S265= | Silent (SNP) | VAF 163/915 reads (18%) | called by muse, mutect2, varscan2
- PHLDB2 | c.2520G>A p.P840= (on ENST00000393925 / NM_001134439.2; = p.P797= on NM_145753.2) | Silent (SNP) | VAF 213/340 reads (63%) | catalogued as rs369065786; called by muse, mutect2, varscan2
- PRKAR2A | c.843C>T p.I281= | Silent (SNP) | VAF 123/408 reads (30%) | catalogued as COSV55551961; called by muse, mutect2, varscan2
- RAD9A | c.456G>T p.L152= | Silent (SNP) | VAF 611/614 reads (100%) | called by muse, mutect2, varscan2
- RALGAPB | c.3993T>A p.G1331= | Silent (SNP) | VAF 110/941 reads (12%) | called by muse, mutect2, varscan2
- SLC8A2 | c.108C>T p.S36= | Silent (SNP) | VAF 159/616 reads (26%) | catalogued as rs749254915; called by muse, mutect2, varscan2
- SPSB2 | c.168C>T p.N56= | Silent (SNP) | VAF 231/487 reads (47%) | called by muse, mutect2, varscan2
- SSTR4 | c.987C>T p.R329= | Silent (SNP) | VAF 58/1609 reads (4%) | called by muse, mutect2
- ST6GAL1 | c.384G>T p.G128= | Silent (SNP) | VAF 106/527 reads (20%) | catalogued as rs776114800; called by muse, mutect2, varscan2
- TENM4 | c.1941C>T p.I647= | Silent (SNP) | VAF 163/1583 reads (10%) | called by muse, mutect2, varscan2
- TMEFF2 | c.27G>A p.Q9= | Silent (SNP) | VAF 138/495 reads (28%) | catalogued as COSV55835112; called by muse, mutect2, varscan2
- TMPRSS12 | c.870C>T p.Y290= | Silent (SNP) | VAF 336/523 reads (64%) | catalogued as rs767272191, COSV68256858; called by muse, mutect2, varscan2
- TRAIP | c.1251C>T p.F417= | Silent (SNP) | VAF 143/502 reads (28%) | catalogued as rs1048291774, COSV58913861; called by muse, mutect2, varscan2
- VRK2 | c.381T>C p.D127= | Silent (SNP) | VAF 94/428 reads (22%) | called by muse, mutect2, varscan2
- WDPCP | c.1179A>T p.L393= | Silent (SNP) | VAF 60/403 reads (15%) | called by muse, mutect2, varscan2
- ZNF595 | c.345A>G p.K115= | Silent (SNP) | VAF 109/416 reads (26%) | called by muse, mutect2, varscan2
- ZNF726 | c.1746G>A p.T582= | Silent (SNP) | VAF 132/501 reads (26%) | catalogued as rs373438470, COSV100484590; called by muse, mutect2, varscan2
- ADGRA1 | c.4-3748G>T | Intron (SNP) | VAF 146/429 reads (34%) | catalogued as rs766988794; called by muse, mutect2, varscan2
- FRMD3 | c.1196-18577T>A | Intron (SNP) | VAF 184/509 reads (36%) | called by muse, mutect2, varscan2
- ZNF772 | chr19:57467076 G>T | 3'Flank (SNP) | VAF 272/417 reads (65%) | called by muse, mutect2, varscan2
